CCDI case PBCMFK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/835f7ece-93dd-4a01-81f3-f7a2908774b2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,792 days).

Biospecimens (3 samples)
- Sample 0DV4IT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV4J2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV4KW: Tissue type: Tumor; Specimen type: Solid Tissue.
